Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7485, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7485-01A (Primary Tumor).

Microscopic Discussion:

Sections demonstrate a mildly hypercellular glial neoplasm that diffusely infiltrates both gray and white matter. The tumor cells have round to oblong nuclei with only mild atypia. Although they do not have prominent glial processes, only rarely are perinuclear halos seen. In the gray matter, the tumor does demonstrate focally prominent perineuronal satellitosis. No mitotic figures are seen. There is no microvascular proliferation or necrosis.

Addendum Discussion:

Only very rare MIB-1 reactive cells are present with an estimated labeling index of <0.1%. There are numerous cells that are immunoreactive for P53. This pattern is most consistent with astrocytoma differentiation.

Final Addendum Diagnosis:

Well-differentiated astrocytoma (WHO grade II)

Source: NCI Genomic Data Commons file 1e6479f1-496b-4c61-a11b-fbc134eb72f4 (TCGA-HT-7485.5AF016F0-9C44-4B57-8477-26E25F087C0F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).